Surgical pathology report (de-identified scan), TCGA case TCGA-FP-7998, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FP-7998-01A (Primary Tumor).

[page 1 of 4]
CLINICAL MANAGER
Patient Results

		M
--	--	---

Surgical Pathology (Copath)	Final
-----------------------------	-------

Path Report	Final
-------------	-------

SURGICAL PATHOLOGY REPORT
ACCESSION NO. :
Final Diagnosis(es):
A) Liver biopsy:
1) Negative for malignancy.
2) No intrinsic liver disease.
(B) "Lymph node", peripancreatic, biopsy: Peritoneal cyst, benign.
(C) Stomach, subtotal gastrectomy:
1) Adenocarcinoma, diffuse type, poorly differentiated.
2) 14 out of 30 perigastric lymph nodes involved by metastatic tumor (14/30).
3) Pathologic stage: pT4aN3a (see Synoptic report, below).
D) Omentum, omentectomy:
1) Adipose and fibrovascular tissue.
2) Negative for malignancy.
Synoptic Report:
Specimen: Stomach.
Procedure: Subtotal gastrectomy.
Tumor Site: Body, lesser curvature.
Tumor Size:
Greatest Dimension: 6.8 cm.
Additional Dimensions: 4.8 x 2.0 cm.
Histologic Type: Adenocarcinoma, diffuse type.
Histologic Grade: G3: Poorly differentiated.
Microscopic Extent of Tumor: Tumor penetrates serosa (visceral peritoneum).
Margins:
Proximal Margin: Uninvolved by invasive carcinoma.
Distal Margin: Uninvolved by invasive carcinoma.
Omental (Radial) Margins: Uninvolved by invasive carcinoma.
Distance of invasive carcinoma from closest margin (proximal margin): 18 mm
Treatment Effect: Not known.
Lymphovascular Invasion: Present.
Pathologic Staging:
Primary Tumor: pT4a: Tumor invades serosa (visceral peritoneum).
Regional Lymph Nodes: pN3a: Metastasis in 7 to 15 perigastric lymph nodes.
Number of Lymph Nodes Examined: 30
Number of Lymph Nodes Involved: 14
Distant Metastasis: Not applicable.

[page 2 of 4]
CLINICAL MANAGER

Patient Results

M

Surgical Pathology (Copath)

Final

Comments:

Cytokeratin (MAK-6) immunohistochemistry stains were performed on blocks C15 and C18, and highlight metastatic tumor cells in lymph nodes.

Electronically Signed

(Fellow)

Specimen(s) Received:

- A: Liver biopsy
- B: Peripancreatic node
- C: Subtotal gastrectomy
- D: Omentum

Clinical History:

Stomach cancer.

(C) Stitch marks proximal margin)

Intraoperative Consultation:

Time Received: 11:07

Time Reported: 11:27

FSA1-FSA2: Liver, no malignancy (2 blocks).

FSC1-FSC4: Subtotal gastrectomy: Chronic inflammation, no tumor (4 blocks).

Gross Description:

(A) (liver biopsy - FS) Received fresh for frozen section evaluation are innumerable fragments and/or cores of soft brown tissue having aggregate dimensions of 1.5 x 0.4 x 0.2 cm. A portion is submitted for frozen section evaluation in cassettes FSA1 and FSA2 with the remainder submitted entirely in cassette A3.

(B) (peripancreatic node) Received in formalin is a single tan, rubbery to soft, and focally fluctuant nodule that is 1.1 x 0.7 x 0.4 cm. The specimen is bisected and expresses greasy, yellow, thin fluid. It is entirely submitted in cassette B1.

(C) (subtotal gastrectomy - FS)

Specimen components and dimensions: Received fresh for frozen section evaluation is a portion of stomach measuring 19.5 cm along the greater curvature, 12.3 cm along the lesser curvature, having a staple line at the proximal end, 9.0 cm long and at the distal end 2.5 cm long. Attached to the greater curvature is gastroomentral fat measuring 28.0 x 8.0 x 2.0 cm and along the lesser curvature cardiac fat that is 9.0 x 5.5 x 4.0 cm.

Size, appearance, and location of tumor: 6.8 distal to proximal by 4.8 cm up to 2.0 cm deep centered along the lesser curvature within the body of the stomach extending up to the antrum.

[page 3 of 4]
[REDACTED] CLINICAL MANAGER		
Patient Results		
[REDACTED]	[REDACTED]	M
[REDACTED]	Surgical Pathology (Copath)	Final

Description of tumor: Ulcerative, endophytic and invasive. The posterior aspect of the serosal surface shows focal adhered omental fat, red-purple discoloration that is inked indigo. Closest resection margins and distance: The proximal margin near the lesser curvature, the tumor appears to be within 1.8 cm.

Gross impression of invasive growth: Deep to the inked serosal margin and corresponding involvement with the lymph nodes within the cardiac lymph node packet.

Other findings: None.

Uninvolved tissues: The gastric mucosa has normal rugae and tenacious brown mucoid material without additional polyps, ulcer or mass.

Lymph nodes attached: From the cardiac lymph node packet are 24 gray-tan, rubbery to firm lymph nodes from 0.3 to 1.8 cm in greatest dimension and an additional 11 black to pale gray-pink, rubbery to soft lymph nodes within the gastrointestinal lymph node packet measuring from 0.3 to 1.9 cm in greatest dimension.

Blocks submitted: Representative sections are taken from the proximal margin that is inked black with FSC1 anterior proximal margin, FSC2 posterior proximal margin, FSC3 and FSC4 represent distal margin, C5-C6 remaining proximal margin near the greater curvature.

C7-C12 - representative sections of tumor with C11 distal interface and C12 proximal interface

C13-C14 - nonneoplastic stomach

C15-C18 - lymph nodes from cardiac lymph node packet with four lymph nodes in C15, six lymph nodes in C16 and C17, and eight lymph nodes in C18

C19-C20 - lymph nodes from gastrointestinal packet with four lymph nodes in C19 and seven lymph nodes in C20

(D) (omentum) Received in formalin is a 13.5 x 13.0 x 6.0 cm portion of finely lobular, pale yellow, fatty tissue and reticulating red-gray, fibrovascular tissue. Sections show no tumor or area of induration. Representative sections are submitted in cassettes D1-D5. [REDACTED]

Microscopic Description:

Complete microscopic evaluation has been performed. [REDACTED]

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the [REDACTED]

[REDACTED] They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These

[page 4 of 4]
CLINICAL MANAGER
Patient Results

		M
Surgical Pathology (Copath)		Final

tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EFGR(31G7), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26). Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per ANP.22998 for a minimum of and a maximum of

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Source: NCI Genomic Data Commons file 941ca120-6bdc-4cad-afe3-0b6331dae0fc (TCGA-FP-7998.5EE15A33-E601-4FF9-BA38-3F0AE949B781.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).